Somatic mutation profile of tumor specimen 0DEP0W from CCDI case PBBRCF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 18.1 years (6,610 days).
Specimen 0DEP0W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19575a73-9809-4e24-be26-0616a8ee3289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEP0Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ce06f7-aa46-4a8e-ba54-4a9023a89b6f

The open-access MAF lists 40 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 6, Nonsense Mutation 1, Splice Region 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TUBA4A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as rs730880026, CM1410435; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 272/1044 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, mutect2, varscan2
- ATP1B1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 236/937 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1304464848, COSV63179399; called by muse, mutect2, varscan2
- ATRNL1 | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 126/535 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782117004, COSV58074209; called by muse, mutect2, varscan2
- LRFN2 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs749352903, COSV57826084; called by muse, mutect2, varscan2
- MTTP | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 276/698 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs761103347, COSV99645030; called by muse, mutect2, varscan2
- MYH14 | c.4721C>T p.A1574V | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.612); catalogued as rs1319422409; called by muse, mutect2, varscan2
- PDE10A | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 194/706 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1463619240; called by muse, mutect2, varscan2
- PIP4K2B | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 326/564 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs543549858; called by muse, mutect2
- PTPRN2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs199560003, COSV67060709; called by muse, varscan2
- TAF1 | c.3475T>C p.Y1159H (on ENST00000373790 / NM_138923.4; = p.Y1180H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV52106796; called by muse, mutect2
- WNT7B | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1158594747; called by muse, mutect2, varscan2
- BVES | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 252/926 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CAPN11 | c.1749C>T p.G583= | Splice Region (SNP) | VAF 58/244 reads (24%) | called by muse, mutect2, varscan2
- DNA2 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 216/670 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ENPP6 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 121/327 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47A | c.1008T>A p.H336Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GALNT5 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 124/477 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPG2 | c.5275G>A p.A1759T | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ITGA1 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 82/869 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAF1 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 271/665 reads (41%) | called by muse, mutect2, varscan2
- RARA | c.864C>G p.D288E | Missense Mutation (SNP) | VAF 191/295 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- WDFY3 | c.7862G>A p.R2621K | Missense Mutation (SNP) | VAF 159/506 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ABCA2 | c.1131G>T p.L377= (on ENST00000614293; = p.L347= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/152 reads (34%) | called by muse, mutect2, varscan2
- CMYA5 | c.681T>C p.Y227= | Silent (SNP) | VAF 64/376 reads (17%) | catalogued as rs778700633; called by muse, mutect2, varscan2
- KIRREL3 | c.1801C>T p.L601= | Silent (SNP) | VAF 90/264 reads (34%) | called by muse, varscan2
- LAMA2 | c.3445C>A p.R1149= | Silent (SNP) | VAF 255/838 reads (30%) | catalogued as COSV70350232; called by muse, mutect2, varscan2
- LAMA4 | c.2802C>A p.V934= (on ENST00000230538 / NM_001105206.3; = p.V927= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 153/697 reads (22%) | called by muse, mutect2, varscan2
- MARCHF4 | c.249C>T p.G83= | Silent (SNP) | VAF 53/268 reads (20%) | catalogued as rs1377933732, COSV56102787; called by muse, mutect2, varscan2
- SOWAHB | c.879C>A p.S293= | Silent (SNP) | VAF 109/283 reads (39%) | called by muse, mutect2, varscan2
- WNK3 | c.1266A>G p.S422= | Silent (SNP) | VAF 91/248 reads (37%) | called by muse, mutect2, varscan2
- ZNF229 | c.1386C>T p.S462= | Silent (SNP) | VAF 66/221 reads (30%) | called by muse, mutect2, varscan2
- ASZ1 | c.1162-94C>T | Intron (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- CNBD2 | c.-38C>A | 5'UTR (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2, varscan2
- COBL | c.1096+19774C>T | Intron (SNP) | VAF 38/870 reads (4%) | called by muse, mutect2
- EIF4B | c.1577-26A>G | Intron (SNP) | VAF 40/654 reads (6%) | called by muse, mutect2
- PGAP3 | c.*892C>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | catalogued as rs879561043; called by muse, mutect2
- PLXNB3 | c.5409+49G>A | Intron (SNP) | VAF 53/66 reads (80%) | catalogued as COSV62798688; called by muse, mutect2, varscan2
- TFR2 | c.2136+71G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- ZNF254 | c.31-46G>T | Intron (SNP) | VAF 104/420 reads (25%) | called by muse, mutect2, varscan2
